Somatic mutation profile of tumor specimen ALCH-AEZR-TTP1-A (aliquot ALCH-AEZR-TTP1-A-3-0-D-A678-36) from ALCHEMIST case ALCH-AEZR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 45.0 years (16,452 days).
Specimen ALCH-AEZR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b04dee4-0db9-48f1-8299-b14747cecd3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEZR-NB1-A (Blood Derived Normal), aliquot ALCH-AEZR-NB1-A-1-0-D-A678-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/928ec9ba-9ed3-427c-af7c-9f9d2b8ee657

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.6253C>A p.Q2085K | Missense Mutation (SNP) | VAF 25/459 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV52114252; called by muse, mutect2
- EPX | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 14/223 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56597733; called by muse, mutect2
- MRGPRF | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1163843209, COSV57995922; called by muse, varscan2
- KIF1B | c.4238C>G p.A1413G (on ENST00000377086 / NM_001365952.1; = p.A1367G on NM_015074.3) | Missense Mutation (SNP) | VAF 14/346 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); called by muse, mutect2
- MUSK | c.943G>T p.G315C | Missense Mutation (SNP) | VAF 20/336 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- INSM2 | c.1122G>A p.G374= | Silent (SNP) | VAF 13/47 reads (28%) | called by muse, mutect2, varscan2
- SULT6B1 | c.57A>G p.K19= | Silent (SNP) | VAF 19/275 reads (7%) | called by muse, mutect2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 6/65 reads (9%) | catalogued as rs201441562; called by pindel, varscan2
